Gene-level copy-number profile of tumor specimen HTMCP-02-03-01002-01A from CGCI case HTMCP-02-03-01002, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.1 years (23,413 days).
Specimen HTMCP-02-03-01002-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 74de9022-c79f-419a-ac4e-ab6a5ced173f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-03-01002-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,745 have no estimate.
https://portal.gdc.cancer.gov/files/b10da9d2-c63d-44fc-b0ae-9b481a232ae4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 53; copy number 2: 19,544; copy number 3: 4,985; copy number 4: 26,593; copy number 5: 2,877; copy number 6: 3,349; copy number 7: 390; copy number 8: 121; copy number 10: 254; copy number 11: 262; copy number 12: 286; copy number 13: 82; copy number 14: 39.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:89,551–91,105, 1 gene (within-gene range 0–4): AL627309.3.
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–2): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr5:148,923,639–149,551,471, 23 genes (within-gene range 0–2): SH3TC2, AC116312.1, RNU6-732P, MIR584, SH3TC2-DT, RN7SKP145, ABLIM3, AC012613.1, AC012613.2, AFAP1L1, AC131025.3, GRPEL2, GRPEL2-AS1, PCYOX1L, IL17B, AC131025.1, CARMN, AC131025.2, MIR143, MIR145, CSNK1A1, AC021078.1, RPL29P14.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr11:98,565,074–100,358,885, 6 genes (within-gene range 0–2): AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 923 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:221,133,865–221,554,314, 5 genes, copy number 10: AL445466.1, LINC02817, AL360013.2, AL360013.3, AL360013.1.
- chr3:163,109,152–163,361,563, 1 gene, copy number 12 (within-gene range 4–12): LINC01192.
- chr3:163,455,568–198,123,232, 626 genes, copy number 11–14 (broad region; genes not listed).
- chr5:24,881,943–45,895,970, 291 genes, copy number 10–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 53. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
